Somatic mutation profile of tumor specimen 0DGUTB from CCDI case PBBTTX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Pineal gland; Age at diagnosis: 2.8 years (1,029 days).
Specimen 0DGUTB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e01b1a36-ad42-44cd-8d0e-ce141ccd66d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGUSA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0af3d4a-61b4-406a-9bfd-1300d5dddb2a

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 26/742 reads (4%) | catalogued as COSV59989381; called by muse, mutect2
- C8B | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 169/568 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371378397; called by muse, mutect2, varscan2
- MAB21L3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 258/793 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs143612563; called by muse, mutect2, varscan2
- PLXNB2 | c.4651C>T p.R1551W | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1252245593, COSV63780100; called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 34/1559 reads (2%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SMARCB1 | c.720_721dup p.E241Gfs*10 (on ENST00000263121; = p.E287Gfs*10 on NM_003073.5) | Frame Shift Ins (INS) | VAF 156/279 reads (56%) | called by mutect2, varscan2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 24/874 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/199 reads (13%) | called by muse, varscan2
